Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1M9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1M9-01A (Primary Tumor).

100-0-3
Adenocarcinoma, NOS 8140/3
Site: Cervix, NOS C53.9 2/25/11
lu

Pathologists: Drs. [REDACTED]

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

Account #: [REDACTED]

DOB/Age: [REDACTED]

Sex: F

Client: [REDACTED]

Ward: [REDACTED]

Rm: [REDACTED]

Physician(s): [REDACTED]

Accession #: [REDACTED]

Procedure Date: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Copies To: [REDACTED]

Specimen(s) Received

A: Cervical, biopsy

B: Endometrium, biopsy

Clinical History

Cervical lesion - Irregular perimenopausal bleeding

Final Pathologic Diagnosis

A, B. CERVICAL BIOPSY AND "ENDO BIOPSY" - POORLY DIFFERENTIATED ADENOCARCINOMA.

Electronic signout

[REDACTED], M.D.

Gross Description

Labeled "cervical" holds granular to nodular tan fragments aggregating to 2 cm, and hemorrhagic material aggregating to 2 cm. RS in A

Labeled "endo" holds tan bits aggregating to 0.5 cm. NS in B

Microscopic Description

Both sections show large fragments of a papillary high grade carcinoma with mixed necrosis and inflammation. Stromal invasion appears to be present. No normal tissue fragments are seen and it is difficult to tell if this is a primary cervical or endometrial tumor. The picture somewhat more suggests an endometrial origin and is consistent with serous carcinoma, but the age of the patient somewhat argues against this.

Billing Fee Code(s): [REDACTED]

SNOMED Code(s): [REDACTED]

(Not Entered)

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 8a1b2d5d-54db-4f5c-a811-cfcbd95b499b (TCGA-C5-A1M9.6D91450A-9499-4B66-90DF-E68B4880E64C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).